Surgical pathology report (de-identified scan), TCGA case TCGA-61-1728, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1728-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, BILATERAL SALPINGO-OOPHORECTOMY -

- A. OVARIAN HIGH GRADE PAPILLARY SEROUS CARCINOMA.
- B. CARCINOMA INVOLVES ENTIRE OVARY, MEASURING 8.0 CM IN GREATEST DIMENSION (GROSS MEASUREMENT).
- C. CARCINOMA WITH SURFACE EXOPHYTIC GROWTH AND OVARIAN STROMA INVASION.
- D. NO LYMPHOVASCULAR INVASION NOTED.
- E. FALLOPIAN TUBE WITH METASTATIC CARCINOMA IN THE PERIPHERAL WALL.

PART 2: ADNEXA, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY -

- A. OVARIAN HIGH GRADE PAPILLARY SEROUS CARCINOMA.
- B. CARCINOMA INVOLVES ENTIRE OVARY, MEASURING 7.0 CM IN GREATEST DIMENSION (GROSS MEASUREMENT).
- C. CARCINOMA WITH SURFACE EXOPHYTIC GROWTH AND OVARIAN STROMA INVASION.
- D. NO LYMPHOVASCULAR INVASION NOTED.
- E. FALLOPIAN TUBE, NO CARCINOMA IDENTIFIED.

PART 3: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY -

- A. METASTATIC CARCINOMA INVOLVES THE UTERINE SEROSA AND SURROUNDING SOFT TISSUE.
- B. INACTIVE ENDOMETRIUM WITH FOCAL GLANDULAR CROWDING.
- C. MYOMETRIUM WITH ADENOMYOSIS.
- D. CERVIX WITH CHRONIC CERVICITIS.

PART 4: PARAMETRIUM, RIGHT, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 5: CUL-DE-SAC, RIGHT, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 6: CUL-DE-SAC, LEFT, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 7: CUL-DE-SAC, POSTERIOR, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 8: SPLEEN, SPLENECTOMY -

- A. SEROUS CARCINOMA INVOLVES SPLEEN CAPSULE AND SURROUNDING SOFT TISSUE; NO SPLEEN PARENCHYMA INVOLVEMENT NOTED.

PART 9: OMENTUM, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 10: PERICOLIC GUTTER, RIGHT, BIOPSY - METASTATIC SEROUS CARCINOMA.

PART 11: APPENDIX, APPENDECTOMY - METASTATIC SEROUS CARCINOMA INVOLVES APPENDIX TIP.

PART 12: STOMACH MESENTERY, BIOPSY - METASTATIC SEROUS CARCINOMA.

COMMENT:

High grade papillary serous carcinoma involves both ovaries and has extensive local extension and peritoneal spreading. I favor the tumor is bilateral ovarian primary with extensive pelvic and peritoneal metastases based on the large tumor volume on both ovaries and the surface exophytic growth and extensive ovarian stroma invasion.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 8 cm
TUMOR TYPE:	Papillary serous carcinoma
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	> 2 cm.
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT3c

N STAGE, PATHOLOGIC: pNX

M STAGE, PATHOLOGIC: pM1

FIGO STAGE: IIIC

Source: NCI Genomic Data Commons file 6c8145a6-515f-4564-9bab-f4a38c96c02a (TCGA-61-1728.7611C4D4-F58B-404E-93F1-949C865C9E12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).